Surgical pathology report (de-identified scan), TCGA case TCGA-D7-8572, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-8572-01A (Primary Tumor).

Material:

1) Material: stomach, Method of collection: Total organ resection

Histopathological diagnosis:

Examination performed on

Adenocarcinoma of the Stomach (G2, pT2, pNO).

Macroscopic description:

The specimen consisting of the stomach sized 25 x 17 cm with the omentum sized 30 x 20 cm. Tumour sized 9 x 5.5 x 1.4 cm found in the central part. The distance from the proximal boundary is 12 cm, from distal boundary, 1 cm.

Microscopic description:

Adenocarcinoma (papillary cystic; G2 - intestinal type according to the Lauren classification) - the tumour infiltrates deep into the muscular membrane (pT2).

Incision lines, omentum and nodes (10) – free of neoplastic lesions.

Assistant:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 7fcc7233-df19-4141-8a99-ab1d866dc3d6 (TCGA-D7-8572.4862AB6E-432E-4CCE-BA69-DF7400475559.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).